Gene-level copy-number profile of tumor specimen C3N-01815-01 from CPTAC case C3N-01815, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.1 years (25,973 days).
Specimen C3N-01815-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 58975e80-1622-40e3-a3cc-140a8b6965c6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01815-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/326be4f1-d0ed-424b-b432-34ca3c0c46ce

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 2: 8,141; copy number 3: 5,594; copy number 4: 35,534; copy number 5: 3,503; copy number 6: 5,602; copy number 9: 1; copy number 22: 2.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–48,599,436, 6 genes (within-gene range 0–2): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1.
- chr17:31,094,927–31,538,211, 12 genes (within-gene range 0–3): NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724.
- chr22:18,527,157–18,611,919, 6 genes: AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:238,777,049–238,779,200, 1 gene, copy number 9: MIPEPP2.
- chr5:180,967,189–180,970,762, 2 genes, copy number 22: AC091874.2, AC091874.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
